Somatic mutation profile of tumor specimen 0DTC63 from CCDI case PBCJKV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.4 years (5,266 days).
Specimen 0DTC63: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27508b82-ca5f-4204-b1da-b636bb9f8276.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTC5V (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7dc995a0-ca6a-448c-93bc-23c34b9c5bbd

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 3, Silent 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 114/536 reads (21%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- DIAPH2 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 185/564 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61271506, COSV61284150; called by muse, mutect2, varscan2
- VIPR1 | c.710G>A p.G237D | Missense Mutation (SNP) | VAF 25/541 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1445366788; called by muse, mutect2
- FCGR3B | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 52/1396 reads (4%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.562); called by muse, mutect2
- GLIPR1L2 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 24/586 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); called by muse, mutect2
- NTNG2 | c.1512_1519del p.A505Gfs*53 | Frame Shift Del (DEL) | VAF 14/179 reads (8%) | called by mutect2, pindel
- PVRIG | c.8C>G p.T3R | Missense Mutation (SNP) | VAF 10/271 reads (4%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); called by muse, mutect2
- RUNDC1 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 90/269 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLN1 | c.6480C>G p.F2160L | Missense Mutation (SNP) | VAF 133/484 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- WNK3 | c.2771dup p.N924Kfs*2 | Frame Shift Ins (INS) | VAF 383/1184 reads (32%) | called by mutect2, varscan2
- IHH | c.972G>T p.V324= | Silent (SNP) | VAF 141/501 reads (28%) | called by muse, mutect2, varscan2
- RYR2 | c.6264C>G p.L2088= | Silent (SNP) | VAF 238/790 reads (30%) | called by muse, mutect2, varscan2
- HEXD | c.982+17C>A | Intron (SNP) | VAF 16/266 reads (6%) | called by muse, mutect2
- LRRIQ1 | c.4007+69A>G | Intron (SNP) | VAF 13/170 reads (8%) | catalogued as rs990198023; called by muse, mutect2
- UQCC1 | c.652-24C>T | Intron (SNP) | VAF 19/522 reads (4%) | called by muse, mutect2
